TCGA case TCGA-PT-A8TR — Sarcoma (TCGA-SARC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Myomatous Neoplasms; Primary site: Corpus uteri; Tissue source site: Maine Medical Center. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/5dbd1eed-523e-48cc-b69b-ac905a1116eb

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 57 years; Vital status: Alive.

Diagnoses (1)
1. Myxoid leiomyosarcoma: ICD-O-3 morphology code: 8896/3; ICD-10 code: C54.0; Tissue or organ of origin: Isthmus uteri; Site of resection or biopsy: Isthmus uteri; Classification of tumor: primary; Age at diagnosis: 57.5 years (20,985 days); Year of diagnosis: 2013; Metastasis at diagnosis: No Metastasis; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R1; Sites of involvement: Uterus; Tumor focality: Unifocal.
   Pathology details: Consistent pathology review: Yes; Margin status: Involved; Necrosis present: No.
   Pathology details: Measurement type: Radiologic; Tumor burden: 20.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 0; Tumor length measurement: 14; Tumor width measurement: 0.
   Pathology details: Measurement type: Pathologic; Tumor burden: 14.
   Pathology details: Measurement type: Radiologic; Measurement unit: Centimeters; Tumor depth measurement: 12; Tumor length measurement: 20; Tumor width measurement: 14.

Follow-up (5 entries)
- Day 0 (initial diagnosis): Discontiguous lesion count: 0.
- Days to follow up: 306 days; Disease response: Tumor Free.
- Days to follow up: 516 days (1.4 years); Disease response: Tumor Free.
- Days to follow up: 624 days (1.7 years); Disease response: Tumor Free.
- Days to follow up: 813 days (2.2 years); Disease response: Tumor Free.

Molecular and laboratory tests
- Test: Mitotic Count Reported; Mitotic count: 3.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-PT-A8TR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 980 mg.
  Slide TCGA-PT-A8TR-01A-01-TS1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-PT-A8TR-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-PT-A8TR-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- Primary pathology: Histologic diagnosis: Leiomyosarcoma (LMS); Histologic subtype: Poorly differentiated or pleomorphic or epithelioid leiomyosarcoma; Margin status: Positive; Tumor total necrosis: 0% (no necrosis or no mention of necrosis); Disease multifocal indicator: No; Discontinuous lesions count: 0; Locoregional recurrence indicator: No; Metastatic disease confirmed: No.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Gynecological - Uterus.
- Primary pathology, Tumor sizes, Tumor size: Lesion pathologic width: 0; Lesion pathologic depth: 0.
- Follow-up form 1: Lost to follow-up: No; Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Response; New tumor event diagnosis indicator: No.
- Drug treatment 1: Treatment on clinical trial: Yes; Days from index date to pharmaceutical treatment started: 40; Days from index date to pharmaceutical treatment ended: 155; Pharmaceutical therapy drug name: Gemzar; Pharmaceutical treatment ongoing indicator: No; Treatment best response: Complete Response.
- Drug treatment 1, Therapy types: Pharmaceutical therapy type: Chemotherapy.
- Drug treatment 2: Treatment on clinical trial: Yes; Days from index date to pharmaceutical treatment started: 40; Days from index date to pharmaceutical treatment ended: 155; Pharmaceutical therapy drug name: Taxotere; Pharmaceutical treatment ongoing indicator: No; Treatment best response: Complete Response.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 813 days; disease-specific survival: no event (censored), 813 days; progression-free interval: no event (censored), 813 days.
